Somatic mutation profile of tumor specimen C3L-08244-03 (aliquot CPT0486500006) from CPTAC case C3L-08244, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G1; Age at diagnosis: 71.1 years (25,964 days).
Specimen C3L-08244-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee972112-c1d4-4000-ac65-b5e6c6ca02ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08244-31 (Blood Derived Normal), aliquot CPT0486630003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b37de1b2-08bf-4cca-a99a-2e6d294c6a9b

The open-access MAF lists 159 somatic variants for this specimen: 115 protein-altering or splice-affecting, 39 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 39, Nonsense Mutation 8, Intron 4, Splice Site 3, Frame Shift Del 3, Frame Shift Ins 2, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 146/344 reads (42%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GNE | c.922C>T p.R308C (on ENST00000396594 / NM_001128227.3; = p.R277C on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/931 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as rs762106720, CM086833, CM139083, COSV64951631; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.277del p.L93Cfs*30 | Frame Shift Del (DEL) | VAF 90/386 reads (23%) | catalogued as rs1567556123, COSV53525400; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABI3BP | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.524); catalogued as rs374566927; called by muse, mutect2, varscan2
- ACADSB | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs754877043; called by muse, mutect2, varscan2
- ACKR1 | c.749T>G p.F250C | Missense Mutation (SNP) | VAF 69/524 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63674502; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 66/441 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs751968200, COSV54999348, COSV54999439; called by muse, mutect2, varscan2
- AMER2 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 95/669 reads (14%) | catalogued as COSV63439902; called by muse, mutect2, varscan2
- ASIC5 | c.592G>C p.A198P | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.425); catalogued as COSV101539775; called by muse, mutect2, varscan2
- ASTN2 | c.3751G>A p.V1251I (on ENST00000313400 / NM_001365069.1; = p.V1200I on NM_014010.5) | Missense Mutation (SNP) | VAF 97/383 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.829); catalogued as rs147429038, COSV104386199; called by muse, mutect2, varscan2
- B4GALNT4 | c.1696C>T p.R566W | Missense Mutation (SNP) | VAF 74/459 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs1417738507; called by muse, mutect2, varscan2
- CCDC168 | c.14326G>A p.V4776I | Missense Mutation (SNP) | VAF 58/412 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.073); catalogued as rs927798070; called by muse, mutect2, varscan2
- CH25H | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100897357; called by muse, mutect2, varscan2
- COL11A1 | c.2510T>A p.L837H | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100614690, COSV62175663, COSV62200150; called by muse, mutect2
- CPXM2 | c.437T>C p.I146T | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV53859542; called by muse, mutect2, varscan2
- DLL3 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 57/355 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs775820811, COSV52693064, COSV52693188; called by muse, mutect2, varscan2
- DNAH11 | c.3835T>C p.Y1279H | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs746381062; called by muse, varscan2
- DNAH5 | c.8770G>A p.A2924T | Missense Mutation (SNP) | VAF 47/393 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs748993870, COSV54205191; called by muse, mutect2, varscan2
- EPPK1 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 123/482 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs782075218, COSV73262224; called by muse, mutect2, varscan2
- EPS8 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 57/293 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99842346; called by muse, mutect2, varscan2
- EYS | c.4780G>T p.A1594S | Missense Mutation (SNP) | VAF 56/455 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.219); catalogued as COSV58196609; called by muse, mutect2, varscan2
- GH2 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 69/467 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs773623624, COSV60426741; called by muse, mutect2, varscan2
- GLB1L3 | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 39/252 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs528826790, COSV68393116; called by muse, mutect2, varscan2
- GRIP1 | c.2846G>A p.G949E (on ENST00000359742 / NM_001379345.1; = p.G897E on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/328 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs768200863; called by muse, mutect2, varscan2
- GSX1 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 52/473 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766872119, COSV57232528; called by muse, mutect2, varscan2
- GUCY1A1 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as rs1353410835, COSV56651646; called by muse, mutect2, varscan2
- ITGA7 | c.1528G>A p.A510T (on ENST00000555728; = p.A466T on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as rs61733964; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNA3 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 76/403 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63902225; called by muse, mutect2, varscan2
- KHDRBS2 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 46/360 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV55431480; called by muse, mutect2, varscan2
- KIAA1217 | c.3955G>A p.V1319I | Missense Mutation (SNP) | VAF 30/544 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs201222136; called by muse, mutect2
- LIMK1 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 70/398 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs782777225; called by muse, mutect2, varscan2
- LRP2 | c.3360G>T p.Q1120H | Missense Mutation (SNP) | VAF 59/374 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99028321; called by muse, mutect2, varscan2
- LRRC37A3 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 30/566 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1439636311; called by muse, mutect2
- MAGEB17 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 145/256 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs763866721, COSV61556951; called by muse, mutect2, varscan2
- MATN2 | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 43/301 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764172338, COSV99646950; called by muse, mutect2, varscan2
- MCF2L2 | c.2435T>C p.I812T | Missense Mutation (SNP) | VAF 50/259 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs1560346660; called by muse, mutect2, varscan2
- MEFV | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 42/394 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs758868622, COSV54823911; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC16 | c.13885G>T p.A4629S | Missense Mutation (SNP) | VAF 57/279 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV101197584; called by muse, mutect2, varscan2
- MYT1 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 60/702 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60501082; called by muse, mutect2
- OR2J1 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 137/406 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs774927957; called by muse, mutect2, varscan2
- OR2J2 | c.10A>T p.K4* | Nonsense Mutation (SNP) | VAF 29/205 reads (14%) | catalogued as rs201438710; called by muse, mutect2, varscan2
- OR2T5 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as rs1302584943; called by mutect2, varscan2
- PADI2 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 81/430 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs754728962, COSV100970969, COSV64945862; called by muse, mutect2, varscan2
- PIEZO2 | c.6498G>T p.E2166D | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs750300884; called by muse, mutect2, varscan2
- PPP6R2 | c.2286-1G>A p.X762_splice (on ENST00000216061 / NM_001365836.1; = p.X735_splice on NM_014678.5 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 30/262 reads (11%) | catalogued as rs1281067023; called by muse, mutect2, varscan2
- PROSER3 | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 54/323 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as COSV56555236; called by muse, mutect2, varscan2
- PTPRC | c.2668C>T p.R890* | Nonsense Mutation (SNP) | VAF 39/334 reads (12%) | catalogued as COSV61407958; called by muse, mutect2, varscan2
- RBMXL2 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 62/339 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as rs750554717, COSV60980351; called by muse, mutect2, varscan2
- RGS9 | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 90/528 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.353); catalogued as rs766188482; called by muse, mutect2, varscan2
- SLC12A5 | c.3071C>T p.P1024L (on ENST00000454036 / NM_001134771.2; = p.P1001L on NM_020708.5) | Missense Mutation (SNP) | VAF 37/664 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs749426883; called by muse, mutect2
- STK24 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 63/540 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs147189846; called by muse, mutect2, varscan2
- TRGV3 | c.143C>A p.T48N | Missense Mutation (SNP) | VAF 160/412 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs552301575; called by muse, mutect2, varscan2
- XKR6 | c.1150C>T p.L384F | Missense Mutation (SNP) | VAF 65/501 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs1246454135; called by muse, mutect2, varscan2
- ZMYM1 | c.1266A>T p.E422D | Missense Mutation (SNP) | VAF 53/355 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs199898245; called by muse, mutect2, varscan2
- ADAMTS12 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 42/349 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- BCAR3 | c.518A>G p.D173G | Missense Mutation (SNP) | VAF 32/253 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- BTNL3 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C1orf56 | c.417T>G p.F139L | Missense Mutation (SNP) | VAF 60/479 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CAPZA2 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 39/357 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- CDC42BPA | c.2350G>A p.D784N | Missense Mutation (SNP) | VAF 91/188 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CHTOP | c.66-12_85del p.X22_splice | Splice Site (DEL) | VAF 120/318 reads (38%) | called by mutect2, pindel, varscan2
- CXorf38 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DLG2 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 89/316 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUOX2 | c.2743G>A p.D915N | Missense Mutation (SNP) | VAF 32/485 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2
- EPC2 | c.2293G>A p.A765T | Missense Mutation (SNP) | VAF 72/352 reads (20%) | SIFT tolerated (0.96); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- EYS | c.3105dup p.G1036Wfs*5 | Frame Shift Ins (INS) | VAF 50/580 reads (9%) | called by mutect2, pindel
- FAM111B | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 56/383 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.04); called by muse, varscan2
- FNDC1 | c.3769G>A p.V1257I | Missense Mutation (SNP) | VAF 71/424 reads (17%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); called by muse, varscan2
- FOLH1 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 67/413 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXC2 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 63/406 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GGA2 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.243); called by muse, mutect2
- GPATCH2 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2
- GPC6 | c.228C>A p.S76R | Missense Mutation (SNP) | VAF 53/491 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- GRIK2 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 31/242 reads (13%) | called by muse, mutect2, varscan2
- HCRTR2 | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 51/360 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- HTT | c.3991T>G p.L1331V | Missense Mutation (SNP) | VAF 22/341 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- IGLV3-12 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 23/195 reads (12%) | called by muse, mutect2, varscan2
- LAIR2 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 72/414 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP12 | c.1514G>T p.G505V | Missense Mutation (SNP) | VAF 45/343 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MSI1 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- MYF5 | c.620T>C p.L207S | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH11 | c.1940A>G p.K647R | Missense Mutation (SNP) | VAF 95/555 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- NDUFC1 | c.174C>T p.L58= | Splice Region (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2, varscan2
- OCA2 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 63/376 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR14K1 | c.788A>T p.D263V | Missense Mutation (SNP) | VAF 34/470 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.203); called by muse, mutect2
- OR5T2 | c.1019T>C p.M340T | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2
- PCDH19 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 73/266 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- PCDHB10 | c.466del p.R156Efs*34 | Frame Shift Del (DEL) | VAF 115/347 reads (33%) | called by mutect2, pindel, varscan2
- POLE | c.801+1G>A p.X267_splice | Splice Site (SNP) | VAF 44/190 reads (23%) | called by muse, mutect2, varscan2
- POLR1C | c.99T>A p.Y33* | Nonsense Mutation (SNP) | VAF 50/444 reads (11%) | called by mutect2, varscan2
- PPP3CC | c.1076A>G p.E359G | Missense Mutation (SNP) | VAF 89/241 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- PRAMEF1 | c.292T>G p.W98G | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- PREX2 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKCB | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 53/386 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- PRSS56 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 163/456 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RAPGEF2 | c.3544A>G p.T1182A | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBMXL1 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 66/730 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2
- RNF38 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 30/1032 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.227); called by muse, mutect2
- RTCB | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RUSC2 | c.2017G>A p.G673S | Missense Mutation (SNP) | VAF 21/672 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2
- SMC1B | c.3374C>A p.S1125* | Nonsense Mutation (SNP) | VAF 68/402 reads (17%) | called by muse, mutect2, varscan2
- SMC2 | c.1484C>T p.T495I | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2
- SPTA1 | c.5972T>A p.L1991Q | Missense Mutation (SNP) | VAF 67/401 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- STK35 | c.601C>G p.R201G | Missense Mutation (SNP) | VAF 64/614 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- TMEM63A | c.1675T>G p.Y559D | Missense Mutation (SNP) | VAF 48/427 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMPRSS13 | c.816C>A p.H272Q | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- TPT1 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 56/586 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2
- TPTE | c.302T>A p.L101Q (on ENST00000618007 / NM_199261.4; = p.L83Q on NM_199259.4) | Missense Mutation (SNP) | VAF 27/461 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRIL | c.2399G>A p.R800K | Missense Mutation (SNP) | VAF 93/440 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- TRIL | c.1850_1856del p.G617Afs*80 | Frame Shift Del (DEL) | VAF 54/400 reads (14%) | called by mutect2, pindel, varscan2
- TTN | c.11248T>G p.S3750A (on ENST00000591111; = p.S3704A on NM_003319.4) | Missense Mutation (SNP) | VAF 50/351 reads (14%) | called by muse, mutect2, varscan2
- TTPA | c.694A>G p.S232G | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- VCP | c.785C>T p.T262I | Missense Mutation (SNP) | VAF 42/534 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF569 | c.1375A>G p.I459V | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- ZRANB3 | c.1980dup p.I661Yfs*4 | Frame Shift Ins (INS) | VAF 63/247 reads (26%) | called by mutect2, pindel, varscan2
- ABHD17C | c.204G>A p.A68= | Silent (SNP) | VAF 29/195 reads (15%) | called by muse, varscan2
- ADGRB1 | c.1299G>A p.T433= | Silent (SNP) | VAF 153/516 reads (30%) | catalogued as rs752254011, COSV60093307; called by muse, mutect2, varscan2
- AHNAK | c.16722G>T p.G5574= | Silent (SNP) | VAF 210/495 reads (42%) | called by muse, mutect2, varscan2
- ARMC5 | c.1563C>T p.R521= | Silent (SNP) | VAF 93/695 reads (13%) | catalogued as rs565385825; ClinVar: likely benign; called by muse, mutect2, varscan2
- BACH2 | c.669C>T p.D223= | Silent (SNP) | VAF 73/467 reads (16%) | catalogued as rs200795787; called by muse, mutect2, varscan2
- CACNA1F | c.2382G>A p.E794= | Silent (SNP) | VAF 73/246 reads (30%) | called by muse, mutect2, varscan2
- CALHM3 | c.768G>A p.A256= | Silent (SNP) | VAF 85/460 reads (18%) | catalogued as rs539780804; called by muse, mutect2, varscan2
- CARS2 | c.744C>T p.P248= | Silent (SNP) | VAF 113/549 reads (21%) | catalogued as rs747726067; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC40 | c.1302C>T p.I434= | Silent (SNP) | VAF 71/202 reads (35%) | catalogued as rs375163840, COSV53898610; called by muse, mutect2, varscan2
- CTDSPL | c.276T>G p.A92= (on ENST00000273179 / NM_001008392.2; = p.A81= on NM_005808.3) | Silent (SNP) | VAF 28/168 reads (17%) | called by muse, mutect2, varscan2
- DZIP1 | c.1665C>T p.T555= (on ENST00000347108; = p.T536= on NM_014934.5) | Silent (SNP) | VAF 45/488 reads (9%) | called by muse, mutect2
- FAT4 | c.7962C>T p.Y2654= | Silent (SNP) | VAF 30/217 reads (14%) | catalogued as rs546465658, COSV58714441; called by muse, mutect2, varscan2
- FCRL3 | c.1479G>A p.L493= | Silent (SNP) | VAF 55/486 reads (11%) | called by muse, mutect2, varscan2
- FRMD1 | c.1398C>T p.A466= | Silent (SNP) | VAF 140/442 reads (32%) | catalogued as rs761874710; called by muse, mutect2
- GTF2F1 | c.954G>A p.E318= | Silent (SNP) | VAF 60/314 reads (19%) | called by muse, varscan2
- H2BC12 | c.282G>A p.E94= | Silent (SNP) | VAF 76/566 reads (13%) | catalogued as rs1436724024; called by muse, mutect2, varscan2
- IL1R1 | c.1674G>A p.E558= | Silent (SNP) | VAF 54/323 reads (17%) | catalogued as COSV99292990; called by muse, mutect2, varscan2
- INPP5J | c.1470G>T p.A490= (on ENST00000331075 / NM_001284285.2; = p.A122= on NM_001002837.2) | Silent (SNP) | VAF 68/395 reads (17%) | called by muse, mutect2, varscan2
- KCNN3 | c.1203C>T p.A401= | Silent (SNP) | VAF 63/532 reads (12%) | catalogued as rs755251545; called by muse, mutect2, varscan2
- KIF1A | c.1494C>T p.N498= | Silent (SNP) | VAF 46/215 reads (21%) | catalogued as rs533472375, COSV100239898; called by muse, varscan2
- KIF2B | c.1137T>C p.D379= | Silent (SNP) | VAF 42/422 reads (10%) | called by muse, mutect2
- LCP2 | c.429G>A p.A143= | Silent (SNP) | VAF 69/371 reads (19%) | catalogued as rs199666234, COSV50454211; called by muse, mutect2, varscan2
- MUC17 | c.11583C>T p.V3861= | Silent (SNP) | VAF 49/337 reads (15%) | catalogued as COSV60298635; called by muse, mutect2, varscan2
- MYT1 | c.177G>A p.K59= | Silent (SNP) | VAF 40/512 reads (8%) | called by muse, mutect2
- NAALAD2 | c.1719G>T p.L573= | Silent (SNP) | VAF 69/270 reads (26%) | called by muse, mutect2, varscan2
- PACSIN2 | c.1263C>T p.D421= | Silent (SNP) | VAF 61/410 reads (15%) | catalogued as rs750117821; called by muse, mutect2, varscan2
- PDZD7 | c.72C>T p.S24= | Silent (SNP) | VAF 100/529 reads (19%) | called by muse, mutect2, varscan2
- PLCL1 | c.2724C>A p.I908= | Silent (SNP) | VAF 36/201 reads (18%) | catalogued as COSV70851136; called by muse, mutect2, varscan2
- PLEKHA7 | c.198G>A p.E66= | Silent (SNP) | VAF 50/268 reads (19%) | called by muse, mutect2, varscan2
- RUNX3 | c.816G>T p.G272= | Silent (SNP) | VAF 76/526 reads (14%) | called by muse, mutect2, varscan2
- SHISA9 | c.711C>T p.N237= | Silent (SNP) | VAF 111/336 reads (33%) | catalogued as rs1206459630, COSV69639536; called by muse, mutect2, varscan2
- SIGLEC8 | c.436C>T p.L146= | Silent (SNP) | VAF 30/280 reads (11%) | catalogued as rs560175596; called by muse, mutect2, varscan2
- SPTB | c.1047C>T p.T349= | Silent (SNP) | VAF 56/257 reads (22%) | catalogued as rs150695302; called by muse, mutect2, varscan2
- TNFSF14 | c.597C>T p.D199= | Silent (SNP) | VAF 74/336 reads (22%) | called by muse, mutect2, varscan2
- TNXB | c.4977G>A p.R1659= (on ENST00000647633; = p.R1412= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/454 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.32178A>G p.P10726= (on ENST00000591111; = p.P9799= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/348 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.22134G>A p.A7378= (on ENST00000591111; = p.A6451= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/238 reads (16%) | catalogued as rs768936623, COSV100633902; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- WDR17 | c.489G>T p.V163= | Silent (SNP) | VAF 54/276 reads (20%) | called by muse, mutect2, varscan2
- ZSCAN25 | c.534C>T p.T178= | Silent (SNP) | VAF 60/396 reads (15%) | catalogued as rs373938589; called by muse, mutect2, varscan2
- CR1 | c.487+12088C>T | Intron (SNP) | VAF 62/555 reads (11%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-372T>A | Intron (SNP) | VAF 31/193 reads (16%) | called by muse, mutect2, varscan2
- PHYHIPL | c.106+642A>C | Intron (SNP) | VAF 70/320 reads (22%) | called by muse, mutect2, varscan2
- SH2D3A | c.1273-17C>A | Intron (SNP) | VAF 88/483 reads (18%) | called by muse, mutect2, varscan2
- TET3 | c.*3169C>T | 3'UTR (SNP) | VAF 54/295 reads (18%) | called by muse, mutect2, varscan2
